Somatic mutation profile of tumor specimen 0DHFOP from CCDI case PBBUHB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 0.4 years (129 days).
Specimen 0DHFOP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f50efc2-b0c5-4ac0-90a9-90f7caee41b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHFL1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd338766-3555-4524-baa3-025e00fb3124

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC9B1 | c.428A>G p.N143S | Missense Mutation (SNP) | VAF 204/484 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781457008; called by muse, mutect2, varscan2
- SHANK2 | c.5521del p.R1841Gfs*3 | Frame Shift Del (DEL) | VAF 177/596 reads (30%) | called by mutect2, pindel, varscan2
